Somatic mutation profile of tumor specimen C3N-00953-03 (aliquot CPT0065440009) from CPTAC case C3N-00953, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.4 years (15,137 days).
Specimen C3N-00953-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 264869aa-bbc0-4a39-8de1-dc2ec6c1bb24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00953-31 (Blood Derived Normal), aliquot CPT0070680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5dda0ce-d542-4473-afe6-35dbda8d3d17

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Intron 4, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 2, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA2 | c.1051A>C p.N351H | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs1185995811, COSV63547281; called by muse, mutect2
- FAM133A | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs1476222624; called by muse, mutect2, varscan2
- FGFR3 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774934127, COSV99601289; called by muse, mutect2, varscan2
- HERC1 | c.13366A>G p.M4456V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs773560667; called by muse, mutect2, varscan2
- PCDHA11 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 64/726 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV56484777; called by muse, mutect2
- PCDHGB1 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 56/556 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs926788481; called by muse, mutect2, varscan2
- PRAG1 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV58164802; called by muse, mutect2, varscan2
- PRAMEF8 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 96/1552 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1347550555; called by muse, mutect2
- PRKCG | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 94/727 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54730150; called by muse, mutect2, varscan2
- RTF1 | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101047824, COSV67478521; called by muse, mutect2
- VHL | c.349dup p.W117Lfs*15 | Frame Shift Ins (INS) | VAF 36/284 reads (13%) | catalogued as COSV56547585; called by mutect2, pindel, varscan2
- ADAMTS1 | c.2566T>A p.S856T | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- BAP1 | c.1009A>T p.K337* | Nonsense Mutation (SNP) | VAF 38/250 reads (15%) | called by muse, mutect2, varscan2
- CADPS | c.3247T>A p.W1083R | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EHBP1L1 | c.1375C>G p.P459A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, varscan2
- GOLGB1 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by mutect2, varscan2
- MAGEA12 | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAGEE2 | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MKLN1 | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MMS19 | c.928T>G p.F310V | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MOG | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); called by muse, mutect2
- PCDH15 | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PDPR | c.1594T>A p.F532I | Missense Mutation (SNP) | VAF 29/448 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.17); called by muse, mutect2
- RNF11 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2
- SMG1 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, mutect2
- TIMM23B | c.530del p.L177Wfs*28 | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, varscan2
- UNG | c.733A>G p.N245D (on ENST00000242576 / NM_080911.3; = p.N236D on NM_003362.4) | Missense Mutation (SNP) | VAF 64/571 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFY | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF600 | c.393_400del p.Q132Yfs*3 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel
- DLG4 | c.1794C>T p.F598= (on ENST00000399506 / NM_001321075.3; = p.F641= on NM_001365.4) | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- EGFL8 | c.138G>A p.P46= | Silent (SNP) | VAF 39/312 reads (13%) | catalogued as rs575900965; called by muse, mutect2, varscan2
- MIGA2 | c.264C>T p.P88= | Silent (SNP) | VAF 47/368 reads (13%) | catalogued as rs538683313; called by muse, mutect2, varscan2
- PCDHB16 | c.1596C>T p.G532= | Silent (SNP) | VAF 61/669 reads (9%) | catalogued as rs782139928, COSV53370404; called by muse, mutect2, varscan2
- RCOR2 | c.192C>T p.P64= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as rs754428923; called by muse, mutect2, varscan2
- RXFP3 | c.714G>A p.T238= | Silent (SNP) | VAF 35/285 reads (12%) | catalogued as rs547132118, COSV57508081; called by muse, mutect2, varscan2
- SMG1 | c.2343C>T p.S781= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- ZNF99 | c.420C>G p.T140= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV68055380; called by muse, mutect2
- AP000769.3 | chr11:65503320 G>A | 5'Flank (SNP) | VAF 9/209 reads (4%) | called by muse, mutect2
- COL18A1 | c.3928+690G>C | Intron (SNP) | VAF 56/449 reads (12%) | catalogued as rs774218242, COSV60587663; called by mutect2, varscan2
- FANCC | c.*26C>T | 3'UTR (SNP) | VAF 34/299 reads (11%) | catalogued as rs770935196; called by muse, mutect2, varscan2
- MALRD1 | c.5030-2387G>T | Intron (SNP) | VAF 22/202 reads (11%) | catalogued as rs1248619060; called by muse, mutect2, varscan2
- MED25 | c.2147-25C>T | Intron (SNP) | VAF 33/229 reads (14%) | catalogued as rs761720007; called by muse, mutect2, varscan2
- PTBP3 | c.-15G>T | 5'UTR (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2, varscan2
- SPINK5 | c.2740-193T>C | Intron (SNP) | VAF 33/299 reads (11%) | catalogued as rs190012161; called by muse, mutect2, varscan2
- ZSWIM8 | c.*208G>C | 3'UTR (SNP) | VAF 26/197 reads (13%) | called by muse, mutect2, varscan2
